Somatic mutation profile of tumor specimen TCGA-AX-A2HH-01A (aliquot TCGA-AX-A2HH-01A-11D-A17D-09) from TCGA case TCGA-AX-A2HH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.0 years (21,924 days).
Specimen TCGA-AX-A2HH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a42ac2fd-489c-427c-89bf-a681326e9585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HH-10A (Blood Derived Normal), aliquot TCGA-AX-A2HH-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/141ef8f9-f816-4772-be56-0125e6764b1e

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 26, Silent 11, Frame Shift Del 3, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>C p.D32A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.394A>C p.T132P | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.26); catalogued as COSV100448747; called by muse, mutect2, varscan2
- AL662899.2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV101021775; called by muse, mutect2, varscan2
- CASKIN2 | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs763984337, COSV100050853; called by muse, mutect2
- CCDC153 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100501558, COSV59541222; called by muse, mutect2, varscan2
- DPY19L2 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs747152353, COSV100193956; called by muse, mutect2, varscan2
- EFTUD2 | c.1585C>A p.R529S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.173); catalogued as COSV101274556, COSV68182821; called by muse, mutect2, varscan2
- EIF4G3 | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); catalogued as COSV99945395; called by muse, mutect2, varscan2
- HEATR1 | c.4709A>G p.D1570G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100857784; called by muse, mutect2, varscan2
- IRX5 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315955; called by muse, mutect2, varscan2
- L1CAM | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs782367123, COSV62826709, COSV62827874; called by muse, mutect2, varscan2
- MAEA | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99295676; called by muse, mutect2, varscan2
- MTM1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs148195763, COSV60333604; called by muse, mutect2, varscan2
- NPAS4 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs368915421; called by muse, mutect2, varscan2
- NRXN3 | c.3262+1G>A p.X1088_splice (on ENST00000335750 / NM_001330195.2; = p.X715_splice on NM_004796.6) | Splice Site (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100208221; called by muse, mutect2
- OR10T2 | c.4C>T p.R2* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV57780538; called by muse, mutect2
- PDPK1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as rs1244284890, COSV99239519; called by muse, mutect2, varscan2
- PHF21A | c.1449C>T p.D483= | Splice Region (SNP) | VAF 19/37 reads (51%) | catalogued as rs1413554947, COSV99139229; called by muse, mutect2, varscan2
- RNF19B | c.1225T>C p.S409P | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99331695; called by muse, mutect2, varscan2
- SPOP | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV61653357, COSV61653952; called by muse, mutect2, varscan2
- SYNE1 | c.17852T>A p.I5951N (on ENST00000367255 / NM_182961.4; = p.I5880N on NM_033071.3) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99576281; called by muse, mutect2, varscan2
- TRIOBP | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as COSV100731085; called by muse, mutect2, varscan2
- ULBP1 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV99998271; called by muse, mutect2, varscan2
- WARS2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1456572950, COSV99346725; called by muse, mutect2, varscan2
- WLS | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs746256483, COSV52049265; called by muse, mutect2, varscan2
- ZNF334 | c.970A>G p.N324D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100749184; called by muse, mutect2, varscan2
- ARID1A | c.5746_5753dup p.S1919Lfs*7 | Frame Shift Ins (INS) | VAF 9/27 reads (33%) | called by mutect2, varscan2
- MAP3K15 | c.3315C>A p.N1105K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.169); called by muse, mutect2
- MERTK | c.171_177del p.G58Sfs*4 | Frame Shift Del (DEL) | VAF 53/98 reads (54%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.260del p.N87Tfs*10 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- TSPAN15 | c.658_665del p.T220Rfs*48 | Frame Shift Del (DEL) | VAF 30/56 reads (54%) | called by mutect2, pindel, varscan2
- ADAP1 | c.975C>T p.I325= | Silent (SNP) | VAF 75/81 reads (93%) | catalogued as COSV99763348; called by muse, mutect2, varscan2
- AMER1 | c.3279G>A p.E1093= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100366947; called by muse, mutect2, varscan2
- BOP1 | c.165C>T p.S55= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs782562547, COSV56640434; called by muse, mutect2, varscan2
- CFAP65 | c.2535C>A p.G845= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100445833; called by muse, mutect2, varscan2
- CYSLTR1 | c.948C>T p.S316= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs748490931, COSV100964750; called by muse, mutect2, varscan2
- FAT4 | c.4722C>A p.T1574= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV67892085; called by muse, mutect2, varscan2
- KCNK9 | c.93G>A p.S31= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100271612; called by muse, mutect2, varscan2
- MUC2 | c.3363C>T p.C1121= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs371296125; called by muse, mutect2, varscan2
- MUC5B | c.10926G>A p.L3642= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV101500696; called by muse, mutect2, varscan2
- MYO1E | c.1395C>T p.D465= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs759846809, COSV55696435; called by muse, mutect2, varscan2
- ZNF536 | c.1941C>T p.V647= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs758459573, COSV100835767; called by muse, mutect2, varscan2
